Gene-level copy-number profile of tumor specimen TCGA-DD-AADQ-01A from TCGA case TCGA-DD-AADQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 59.6 years (21,756 days).
Specimen TCGA-DD-AADQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.7f41d322-5cd5-4ea9-8798-e16d5a3fd92e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/337669f6-7da9-452a-bfc4-6c4f06f06cbf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 6,775; copy number 2: 46,561; copy number 3: 243; copy number 4: 6,222; copy number 5: 4; copy number 7: 4; copy number 9: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADQ-01A-11D-A40Q-01): tumor purity 0.85, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,249,838–39,304,898, 2 genes (within-gene range 0–2): AL442071.1, HSPE1P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,004,316–36,121,683, 2 genes, copy number 5 (within-gene range 1–5): AC124290.2, AC124290.3.
- chr8:37,326,575–37,406,724, 2 genes, copy number 5: AC091182.1, AC091182.2.
- chr8:41,840,059–42,171,673, 8 genes, copy number 7–9 (within-gene range 4–9): RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2.

Autosomal genes at a single copy (total copy number 1): 4,388. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
